Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6680, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6680-01A (Primary Tumor).

[page 1 of 3]
[illegible]

Clinical Diagnosis & History:
■ year old female with colorectal carcinoma.

DIAGNOSIS:

1. Right hemicolectomy:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Cecum

Tumor Size:

Length is 3 cm

Width is 3.4 cm

Maximal thickness is 1.1 cm

Tumor Budding:

Focal

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubulovillous adenoma

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

Not Identified

Non-Neoplastic Bowel:

Unremarkable

Appendix:

Not identified

Lymph Nodes:

Number with metastasis: 4

Total number examined: 17

Tumor deposits in pericorectal soft tissue:

** Continued on next page **

[page 2 of 3]
Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N2a (Metastasis in 4-6 regional lymph nodes)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh, labeled "Right hemicolectomy" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 11.5 cm in length and 3.0 cm in circumference at the proximal resected margin. The remaining colon measures 20.0 cm in length with a circumference of 7.0 cm at the distal resected margin. There is no attached appendix, and serosa displays a 0.7 x 0.5cm white ill-defined fibrotic focus of a possible previous appendectomy site which is submitted. The intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 4.5 cm in thickness. The specimen is opened to reveal a papillary tumor measuring 3.0 Cm in length and 3.4 Cm in width. The tumor is located distal to the cecum, 3.2cm from the ileocecal valve, 14.8 cm from the proximal margin and 15.0 cm from the distal margin. Sectioning shows that the tumor invades to a depth of 1.1cm grossly extending into the muscularis. The remaining mucosa is otherwise tan yellow and grossly unremarkable. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for

Summary of sections:

PM - proximal margin shave

DM - distal margin shave

T - tumor

A - possible previous appendectomy site

RS -representative sections

LN - lymph nodes

BLN - bisected lymph nodes

** Continued on next page **

[page 3 of 3]
Summary of Sections:

Part 1: Right hemicolectomy

Block	Sect.	Site	PCs
1		A	1
2		DM	2
7		LN	17
1		PM	1
1		RS	1
3		T	3

** End of Report **

Source: NCI Genomic Data Commons file 9028d496-147d-49e2-8a6d-9233b34810e3 (TCGA-CM-6680.5FB9EB48-80CA-443A-812D-41F59B9A91EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).